Gene-level copy-number profile of tumor specimen C3L-01884-02 from CPTAC case C3L-01884, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,320 days).
Specimen C3L-01884-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78769c6c-dd4e-4a5c-bd51-a2cdd4832b72.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01884-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/f15a61a4-f2de-4dd6-a2a5-001ebac35cff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 496; copy number 1: 21,457; copy number 2: 32,209; copy number 3: 3,916; copy number 4: 738; copy number 5: 17; copy number 6: 6; copy number 9: 48; copy number 17: 9; copy number 19: 1; copy number 25: 16.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,088,457, 8 genes (within-gene range 0–1): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2.
- chr5:156,458,398–157,059,119, 7 genes (within-gene range 0–1): AC027308.1, AC025434.1, RNU6-556P, PPP1R2B, TIMD4, APOOP1, HAVCR1.
- chr11:63,046,785–63,048,126, 1 gene: TUBAP7.
- chr17:18,450,244–18,475,920, 4 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 96 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:196,868–524,449, 16 genes, copy number 5: CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1.
- chr8:37,326,575–39,522,852, 68 genes, copy number 6–25 (broad region; genes not listed).
- chr8:43,442,902–43,544,057, 7 genes, copy number 9: AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2.
- chr22:15,282,557–15,350,043, 5 genes, copy number 6: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 19,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
